Gene-level copy-number profile of tumor specimen C3N-02290-01 from CPTAC case C3N-02290, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 51.7 years (18,896 days).
Specimen C3N-02290-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c2135afe-d109-4143-9f0c-bfe29f0a8bc3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02290-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/44d09d92-6497-484c-84dd-c2559ecf5691

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 3,336; copy number 2: 18,580; copy number 3: 14,932; copy number 4: 13,923; copy number 5: 6,188; copy number 6: 508; copy number 7: 442; copy number 8: 552; copy number 9: 172; copy number 10: 29; copy number 11: 61; copy number 12: 69; copy number 14: 63; copy number 15: 27; copy number 16: 14.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–2): RPS3AP15.
- chr5:59,039,761–59,063,503, 1 gene (within-gene range 0–3): AC092343.1.
- chr5:180,967,189–180,982,611, 3 genes: AC091874.2, AC091874.1, ARPP19P1.
- chr8:89,412,621–89,415,071, 1 gene: KRT8P4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,125 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,259,568–31,364,953, 4 genes, copy number 6: SNRNP40, AC114495.2, ZCCHC17, AL451070.1.
- chr1:39,955,112–54,887,195, 449 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:64,384,398–65,641,559, 25 genes, copy number 5: RNU7-62P, CACHD1, MIR4794, RAVER2, JAK1, AL606517.2, AL606517.1, LINC01359, SLC2A3P2, AL357078.2, RNU6-1176P, MIR3671, MIR101-1, AL357078.1, MRPS21P1, AK4, RPS29P7, DNAJC6, AL139294.1, COX6CP13, RNU2-15P, LEPROT, LEPR, AC119800.1, AC097063.1.
- chr1:143,419,625–248,937,043, 2,524 genes, copy number 5 (broad region; genes not listed).
- chr3:147,386,046–198,123,232, 891 genes, copy number 5 (broad region; genes not listed).
- chr4:49,486,926–49,589,529, 12 genes, copy number 5: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr5:58,198–438,291, 15 genes, copy number 5 (within-gene range 1–5): AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1.
- chr5:470,456–45,895,970, 660 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr7:54,419,444–54,578,794, 4 genes, copy number 5: SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1.
- chr8:7,418,991–8,244,865, 57 genes, copy number 5: HSPD1P3, DEFB103B, SPAG11B, DEFB104B, DEFB106B, DEFB105B, DEFB107B, PRR23D1, FAM90A6P, FAM90A7P, FAM90A21P, FAM90A22P, FAM90A23P, OR7E157P, AC134684.1, AC084121.1, OR7E154P, FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P, FAM90A19P, FAM90A9P, FAM90A10P, PRR23D2, PRR23D3P, DEFB107A, DEFB105A, DEFB106A, DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1, AC105233.4, AC105233.2, MIR548I3, RPS3AP31, SNRPCP17, ENPP7P1, FAM85B, AC068020.1, FAM86B3P, ALG1L13P.
- chr8:46,028,804–54,355,118, 122 genes, copy number 6–10 (broad region; genes not listed).
- chr8:56,436,674–81,924,348, 384 genes, copy number 5–16 (broad region; genes not listed).
- chr8:82,098,451–82,160,577, 1 gene, copy number 12: LINC02839.
- chr8:103,371,538–106,752,694, 39 genes, copy number 10–11 (within-gene range 3–11): CTHRC1, AC012213.3, RNU6-1011P, SLC25A32, AC012213.5, DCAF13, AC012213.2, AC012213.4, AC012213.1, RIMS2, PTMAP15, AC007751.1, AC090686.1, DPYS, DCSTAMP, AP003471.1, AP002847.1, MIR548A3, LRP12, NDUFA5P2, ZFPM2, AC012564.1, AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1.
- chr8:116,402,543–116,403,757, 1 gene, copy number 10: AC105177.1.
- chr8:121,380,137–121,380,465, 1 gene, copy number 10: RPL35AP19.
- chr8:121,639,293–133,326,404, 176 genes, copy number 5–11 (within-gene range 4–11) (broad region; genes not listed).
- chr9:60,914,407–62,845,184, 53 genes, copy number 7: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2, RN7SL722P, FAM27C, AL391987.2, AL391987.1, AL391987.4, AL391987.3, Y_RNA, FAM242E, CR769775.1, AL590399.4, AL590399.3, AL590399.6, SNORA70, RN7SL544P, AL590399.1, FGF7P6, AL590399.5, AL590399.2, BX664725.1, LINC01189, FGF7P7, BX005266.2, BX005266.1, CNTNAP3P5, RBPJP7, RAB28P2, BX005266.3, ATP5F1AP7, SDR42E1P3, FKBP4P7, LINC01410, AL512625.3, RNA5SP283, AL512625.2, PTGER4P2, CDK2AP2P2.
- chr11:66,070,272–73,142,318, 282 genes, copy number 5–9 (broad region; genes not listed).
- chr11:73,876,699–76,144,232, 86 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr12:31,244,440–34,249,958, 82 genes, copy number 5–9 (broad region; genes not listed).
- chr14:18,333,726–19,489,148, 53 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10, NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2, POTEM, AL929601.3, RNU6-1239P, AL589182.1, GRAMD4P4, DUXAP9, AL589182.3, AL589743.3, NBEAP5, AL589182.2, OR11H13P, AL589743.2, AL589743.4, CDRT15P13, NBEAP6, AL589743.1, TOMM40P1, DUXAP10, BMS1P17, AL929602.1, LINC01297, GRAMD4P3, POTEG, AL512624.2, RNU6-1268P, MED15P6.
- chr14:20,505,537–20,560,931, 4 genes, copy number 8: RNASE10, PTCD2P1, SETP1, RNASE9.
- chr14:28,264,390–29,500,460, 21 genes, copy number 6 (within-gene range 2–6): BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1, LINC02326, Y_RNA, AL135878.1, RNU6-864P, AL133166.1, AL158058.1, AL158058.2.
- chr14:29,940,745–30,297,043, 3 genes, copy number 6 (within-gene range 2–6): AL133372.3, AL133372.2, AL133372.1.
- chr14:30,874,514–37,172,606, 123 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr14:38,605,255–53,157,528, 213 genes, copy number 7 (broad region; genes not listed).
- chr17:11,197,883–12,215,267, 13 genes, copy number 6: AC005548.1, SHISA6, AC005725.1, DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2.
- chr17:33,013,087–34,174,964, 1 gene, copy number 5 (within-gene range 3–5): ASIC2.
- chr17:33,529,787–83,240,804, 1,796 genes, copy number 5–6 (broad region; genes not listed).
- chr19:20,432,552–20,571,095, 2 genes, copy number 5 (within-gene range 2–5): AC008554.1, BNIP3P23.
- chr21:7,744,962–8,680,934, 28 genes, copy number 7: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2.

Autosomal genes at a single copy (total copy number 1): 537. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
